Surgical pathology report (de-identified scan), TCGA case TCGA-55-8514, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8514-01A (Primary Tumor).

[page 1 of 4]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

- A. - C.) LUNG, RIGHT, UPPER LOBE, UPPER PARATRACHEAL (N2R), AND LOWER PARATRACHEAL (N4R) LYMPH NODES, LOBECTOMY AND LYMPH NODE DISSECTION:
- MODERATELY DIFFERENTIATED ADENOCARCINOMA.
- 4.1 cm in maximum dimension.
- Visceral pleural invasion: NOT IDENTIFIED.
- MARGIN STATUS: NEGATIVE.
- SEVEN LYMPH NODES, NEGATIVE FOR METASTASIS (0/7).
- SEE TUMOR STAGING SUMMARY BELOW.

PATHOLOGIC TUMOR STAGING SUMMARY:

Type and grade: Invasive adenocarcinoma, moderately differentiated.
Primary tumor: pT2a (4.1 cm in maximum dimension).
Regional lymph nodes: pN0 (seven lymph nodes, negative for metastasis).
Distant metastasis: Not applicable.
Pathologic stage: IB.
Lymphovascular invasion: Not identified.
Margin status: R0.

Lung Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, [REDACTED] and CAP protocol, [REDACTED]

[page 2 of 4]
Procedure:	Lobectomy.
Specimen type:	Lung, upper lobe.
Specimen laterality:	Right.
Specimen integrity:	Intact.
Tumor Features:	
Tumor site:	Right lung, upper lobe.
Tumor size:	Greatest dimension: 4.1 cm. Additional dimensions: 3.1 x 2.3 cm.
Tumor focality:	Unifocal.
Histologic type:	Adenocarcinoma.
Histologic grade:	Moderately differentiated (G2).
Lymphovascular invasion:	Not identified.
Perineural invasion:	Not identified.
Visceral pleural invasion:	Not identified.
Tumor extension into extra-pulmonary structures:	Absent.
Treatment effect:	Not applicable.
Lymph Nodes:	Seven lymph nodes, negative for metastasis.
Margin Evaluation:	Negative (R0).
Distance to closest margin:	2.5 cm from the bronchial margin.
Bronchial margin:	Uninvolved by carcinoma.
Vascular margin:	Uninvolved by carcinoma.
Parenchymal margin:	Uninvolved by carcinoma.
Parietal pleural margin:	Not applicable.
Chest wall margin:	Not applicable.
Other margins:	Not applicable.
Pathologic tumor staging descriptors:	
Primary tumor (pT):	pT2a (4.1 cm in maximum dimension).
Regional lymph nodes (pN):	pN0 (0/7 lymph nodes).
Distant metastasis (pM):	Not applicable.
Margin status (R):	R0.
Pathologic stage:	IB.
Additional pathologic findings:	Emphysematous changes.
Comment:	Not applicable.

[page 3 of 4]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Lung; Right lung upper lobe
- B. Lymph node; Right lung 2R node
- C. Lymph node; 4R node

Clinical History/Operative Dx:

Lung cancer upper right side (right upper lobe)

Gross Description:

A. Received in formalin is a 122 gram right upper lobe of lung, 12.7 x 11.5 x 3.8 cm. The pleura is glistening, deep purple to light pink and tan. The main bronchial margin(s) extend out to 0.7 cm, an aggregate of 1.8 cm in diameter, grossly uninvolved with tumor.

Within 2.5 cm of the bronchial margin a palpable mass is appreciated, and the overlying associated pleura is now marked blue. Sectioning reveals an irregular, fairly well demarcated, light to deep gray tumor mass, measuring upwards of 4.1 x 3.1 x 2.3 cm. The lesion abuts the overlying pleura. A representative portion of tumor, paraneoplastic, and normal uninvolved lung are submitted for Oncogenotyping studies. The remaining cut sections of the lung demonstrates consolidated, deep red parenchyma and spongy light pink and tan tissue, with moderate anthracotic pigmentation. No additional nodularity appreciated. Representative sections are submitted for microscopic evaluation.

Cassette summary: A1) bronchial and vascular margins represented, A2) two hilar-interlobar lymph node candidates, one bisected (blue), one intact (orange), A4-A5) representation of tumor mass and adjacent pleura, A6) tumor mass, adjacent uninvolved lung, A7) consolidated and fibrotic lung represented.

B. Part B designated right lung, 2R node. Received in formalin are two light pink to speckled dark gray lymph node candidates, 0.6 x 0.4 cm and 0.8 x 0.4 cm each. Multiple lymph nodes are submitted for microscopic evaluation in B1.

C. Part C designated right lung, 4R node. Received in formalin are two lymph node candidates, 1.5 x 0.6 cm and 2.4 x 1.3 cm each. Sectioning through both nodes demonstrates a deep pink to dark gray speckled cut surface. The larger node is submitted trisected in C1 and the smaller node bisected and in C2.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Four peribronchial lymph nodes are present, negative for metastasis.

B. Sections demonstrate one lymph node, negative for metastasis

C. Sections demonstrate two lymph nodes, negative for metastasis

[page 4 of 4]
FINAL SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file 36c7c40a-8679-4d3e-9c60-507d71b6aa7f (TCGA-55-8514.C2DF4F99-8079-4900-98EB-B9117EF05467.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).